Somatic mutation profile of tumor specimen MP2PRT-PAVIDY-TMP1-A (aliquot MP2PRT-PAVIDY-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVIDY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,871 days).
Specimen MP2PRT-PAVIDY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0615ea1e-ed8e-45b4-8cec-0335a17d5a85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVIDY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVIDY-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6de93cd-a2a5-4371-86f3-875521637ebb

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASCC1 | c.383A>G p.D128G (on ENST00000342444 / NM_001369085.1; = p.D100G on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs764700294; called by muse, mutect2, varscan2
- C14orf132 | c.273G>T p.L91F (on ENST00000553782 / NM_001289139.2; = p.L60F on NM_001252507.3) | Missense Mutation (SNP) | VAF 170/435 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SNCAIP | c.981A>C p.K327N | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TMEM225B | c.265A>C p.T89P | Missense Mutation (SNP) | VAF 159/446 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF263 | c.1581C>A p.F527L | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GABRG3 | c.222C>T p.D74= | Silent (SNP) | VAF 35/162 reads (22%) | catalogued as rs763876355, COSV61510806, COSV61532494; called by muse, mutect2, varscan2
